Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N6, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N6-01A (Primary Tumor).

[page 1 of 2]
(Specimen Collected:

Comment for
HISTOPATHOLOGY REPORT

HISTOLOGY

REQUEST DETAILS

Distal gastrectomy for gastric adenocarcinoma.

MACROSCOPIC DESCRIPTION

Specimen labelled distal gastrectomy. A portion of stomach 100x60x30mm with stapled proximal and distal resection margins. The proximal margin is 90mm in diameter, and the distal margin is 30mm. Adipose tissue is attached to the lesser and the greater curvatures of the specimen. Margins marked with black ink. Approximately 10mm from the distal resection margin is an ulcerated raised tumour measuring 60x45mm which is predominantly on the greater curvature of the specimen. Enlarged lymph nodes are palpable adjacent to the gastric antrum. The remainder of the gastric mucosa is unremarkable. The tumour is 40mm from the proximal resection margin. Blocks selected 1.1 and 1.2 proximal resection margin, 1.3 - 1.5 composite section of tumour commencing with distal resection margin, 1.6 lesser curvature nodes, 1.7 - 1.10 greater curvature nodes.

MICROSCOPIC DESCRIPTION

Sections from the macroscopically described tumour show an invasive moderately and poorly differentiated adenocarcinoma. The tumour is centrally ulcerated, and comprises irregular glandular structures formed by atypical cuboidal to columnar epithelial cells. In some areas, there are solid sheets of tumour cells with only occasional small glandular spaces. Tumour invades into muscularis propria, but is clear of the serosal surface. There is focal lymphovascular and perineural permeation. Proximal and distal resection margins are clear of tumour. There is metastatic adenocarcinoma within 10 of 20 lymph nodes retrieved from the greater curve. Four (4) lymph nodes from the lesser curve show no evidence of metastatic carcinoma. The largest involved node is 25mm in diameter, and there is extracapsular extension to a distance of approximately 1mm. Tumour is also present within lymphovascular spaces in adjacent fat. The gastric mucosa away from the tumour shows a mild chronic inflammatory cell infiltrate within superficial lamina propria, including lymphocytes and plasma cells. Scattered lymphoid follicles are present, and there is also focal acute inflammation. Although the pattern of inflammation is in keeping with Helicobacter infection, Helicobacter pylori are not identified within surface mucin. There is intestinal metaplasia within the antrum. The proximal duodenum is unremarkable.

DIAGNOSIS

Distal gastrectomy - Moderately and poorly differentiated adenocarcinoma of gastric antrum, invading into muscularis propria, clear of proximal and distal margins, with lymphovascular and perineural permeation, and metastases in 10 of 24 lymph nodes. Adjacent mild active chronic gastritis and focal intestinal metaplasia.

Handwritten notes:
Adenocarcinoma, intestinal type 8/4/13
Site: Gastric antrum 016.3
Greater curvature of stomach 016.6
0202/2/14

Handwritten note: Per TSS, dx discrepancy from
Status TCGA tumor to be
adenocarcinoma, intestinal type. BCK

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

1100

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report.	adenocarcinoma, NOS	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	adenocarcinoma, intestinal type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subtype not specified in path report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file fdf4f05d-ac2a-4caa-a425-efc0e6ddcc50 (TCGA-RD-A8N6.DD9DFC5C-9083-4C54-8085-FF6CB44C95C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).